Somatic mutation profile of tumor specimen TCGA-MP-A4T6-01A (aliquot TCGA-MP-A4T6-01A-32D-A25L-08) from TCGA case TCGA-MP-A4T6, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.6 years (27,993 days).
Specimen TCGA-MP-A4T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fa2c611-fe96-41ec-8a00-2b46cd730896.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T6-10A (Blood Derived Normal), aliquot TCGA-MP-A4T6-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1b83294-f226-4a26-b60c-601ea22ba6b0

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Nonsense Mutation 5, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 27/116 reads (23%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- ADRA1A | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 25/476 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767695098, COSV52356985; called by muse, mutect2
- AGO4 | c.2351T>C p.L784P | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100943120; called by muse, mutect2, varscan2
- AHNAK2 | c.11507A>G p.D3836G | Missense Mutation (SNP) | VAF 236/520 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100319186; called by muse, mutect2, varscan2
- ARFIP2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99601623, COSV99601708; called by muse, mutect2
- ATG4C | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100508614; called by muse, mutect2, varscan2
- BCL2L10 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99548650; called by muse, mutect2, varscan2
- CD180 | c.1587C>A p.H529Q | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99842146; called by muse, mutect2, varscan2
- CDHR3 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as rs749341687, COSV100488944, COSV58420174; called by muse, mutect2, varscan2
- CEP95 | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV101616348; called by muse, mutect2
- CHPF2 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as COSV99223395; called by muse, mutect2, varscan2
- CRB1 | c.3856C>G p.R1286G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV66328778; called by muse, mutect2, varscan2
- CTNND2 | c.1715C>G p.A572G | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100481583; called by muse, mutect2, varscan2
- DNAH5 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99454512; called by muse, mutect2, varscan2
- DOCK2 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99916052; called by muse, mutect2
- DUSP4 | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530134; called by muse, mutect2, varscan2
- FHOD1 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99264594; called by muse, mutect2, varscan2
- FLG | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV100912211, COSV64251639; called by muse, mutect2
- FOXF1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99296825; called by muse, varscan2
- GCM2 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV101069645, COSV65276363; called by muse, mutect2, varscan2
- GK2 | c.956A>C p.E319A | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726060; called by muse, mutect2, varscan2
- H2AC11 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100345898, COSV60362514; called by muse, mutect2, varscan2
- HIVEP3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56015368, COSV56017375; called by muse, mutect2
- HMCN1 | c.10048G>T p.E3350* | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | catalogued as COSV54925209, COSV99637037; called by muse, mutect2, varscan2
- IFT172 | c.3649C>T p.Q1217* | Nonsense Mutation (SNP) | VAF 44/220 reads (20%) | catalogued as COSV99563548; called by muse, mutect2, varscan2
- IFT172 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868020223, COSV99563550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL17RC | c.1945G>T p.V649F (on ENST00000295981 / NM_153461.4; = p.V563F on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99926081; called by muse, mutect2, varscan2
- KIF13A | c.2147T>G p.L716R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99438592; called by muse, mutect2, varscan2
- KIR2DL4 | c.730G>A p.E244K (on ENST00000396284; = p.E205K on NM_001080770.2) | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs1393316406; called by muse, varscan2
- MAGIX | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100891942; called by muse, mutect2
- MARF1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100706448; called by muse, mutect2, varscan2
- MDN1 | c.5158A>C p.N1720H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV101021904; called by muse, varscan2
- MUC16 | c.14780T>C p.V4927A | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV101202001; called by muse, mutect2
- MYLK | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs1433300131, COSV100659767; called by muse, mutect2, varscan2
- NCAM1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as COSV57515835; called by muse, mutect2, varscan2
- NDOR1 | c.637A>G p.M213V | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs937940405, COSV100789102; called by muse, mutect2, varscan2
- NIN | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99815615; called by muse, mutect2, varscan2
- ODF3L1 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.054); catalogued as rs751580364, COSV100150858; called by muse, mutect2, varscan2
- OLFML2B | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1421966218, COSV54195125, COSV54199204; called by muse, mutect2, varscan2
- OR13D1 | c.603T>A p.C201* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV100598770; called by muse, mutect2, varscan2
- OR2A14 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371499311; called by muse, mutect2
- PDE4A | c.1087G>C p.E363Q (on ENST00000380702 / NM_001111307.2; = p.E124Q on NM_006202.3) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99535389; called by muse, mutect2, varscan2
- PKHD1 | c.10483C>T p.L3495F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.312); catalogued as COSV64381618; called by muse, varscan2
- PLEKHA7 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as rs1220851124, COSV100850470; called by muse, mutect2, varscan2
- PRDM9 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690884, COSV99691432; called by muse, mutect2, varscan2
- PROSER3 | c.1268G>C p.R423T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99994823; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV99770593; called by muse, mutect2, varscan2
- RABEP2 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV100707263; called by muse, mutect2, varscan2
- RNF213 | c.8068G>A p.G2690R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745353314, COSV100301649; called by muse, mutect2
- SESN2 | c.941G>A p.C314Y | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.36); catalogued as COSV99456274; called by muse, mutect2, varscan2
- SIRT3 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101236030; called by muse, mutect2, varscan2
- TCF25 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 60/202 reads (30%) | catalogued as COSV54527043, COSV99643520; called by muse, varscan2
- TNR | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99691963; called by muse, mutect2, varscan2
- TSFM | c.101T>A p.F34Y | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100103807; called by muse, mutect2, varscan2
- UNC13A | c.3404A>G p.K1135R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV99409782; called by muse, mutect2
- UNC13B | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100266947; called by muse, mutect2, varscan2
- ZNF395 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765804551, COSV60430396; called by muse, mutect2, varscan2
- ANKRD6 | c.942G>A p.V314= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100330370; called by muse, mutect2, varscan2
- CECR2 | c.1344C>T p.D448= (on ENST00000342247 / NM_001290047.2; = p.D265= on NM_001290046.1) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs374304753; called by muse, mutect2, varscan2
- CELSR3 | c.2817A>G p.P939= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99375264; called by muse, mutect2, varscan2
- CHPF2 | c.2241C>T p.L747= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99223397; called by muse, mutect2, varscan2
- COL6A3 | c.3406C>T p.L1136= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99802074; called by muse, mutect2, varscan2
- COL9A3 | c.1170C>T p.L390= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs770072884, COSV100673617; called by muse, mutect2
- DCUN1D4 | c.867A>G p.K289= (on ENST00000334635 / NM_001287757.1; = p.K254= on NM_015115.3) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100584752; called by muse, mutect2, varscan2
- DOCK7 | c.3684G>A p.R1228= (on ENST00000635253 / NM_001367561.1; = p.R1197= on NM_033407.3) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99226251; called by muse, mutect2, varscan2
- FHOD1 | c.930C>G p.V310= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as COSV99264590; called by muse, mutect2, varscan2
- GMIP | c.825C>T p.V275= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99179660; called by muse, mutect2
- KAT14 | c.1458G>A p.P486= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs375037838; called by muse, mutect2
- KCNK3 | c.366C>T p.L122= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as rs61736657, COSV57193562; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.9945C>T p.S3315= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV67469088; called by muse, mutect2, varscan2
- MUC5B | c.5013G>A p.T1671= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs566512627, COSV101500866; called by muse, mutect2, varscan2
- OPRK1 | c.729C>T p.I243= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1413016291, COSV55575408; called by muse, mutect2, varscan2
- PTCD1 | c.1278C>T p.L426= | Silent (SNP) | VAF 100/336 reads (30%) | catalogued as COSV99464649; called by muse, mutect2, varscan2
- PTPRN2 | c.2373G>A p.A791= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as rs267601435; called by muse, mutect2, varscan2
- SP7 | c.369C>A p.P123= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV100382130; called by muse, mutect2, varscan2
- TBC1D9B | c.1335G>T p.A445= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV100783685; called by muse, mutect2, varscan2
- TCF25 | c.1926G>A p.L642= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as rs1397687983, COSV54531167, COSV99643517; called by muse, varscan2
- TRIM42 | c.324C>G p.L108= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99648927; called by muse, mutect2, varscan2
- MAP4 | c.1999+5499C>T | Intron (SNP) | VAF 7/63 reads (11%) | catalogued as rs772185362, COSV99275093, COSV99275311; called by muse, varscan2
